Somatic mutation profile of tumor specimen TCGA-D8-A1XU-01A (aliquot TCGA-D8-A1XU-01A-11D-A14K-09) from TCGA case TCGA-D8-A1XU, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IA; Age at diagnosis: 56.7 years (20,715 days).
Specimen TCGA-D8-A1XU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1c86497b-f3a6-4bc3-a415-3cc2be22793e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D8-A1XU-10A (Blood Derived Normal), aliquot TCGA-D8-A1XU-10A-01D-A14K-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4c544fc5-9a96-4e89-bb01-797692a48967

The open-access MAF lists 26 somatic variants for this specimen: 18 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 7, Nonsense Mutation 2, 3'UTR 1, Frame Shift Del 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKT1 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 33/50 reads (66%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121434592, COSV62571334, COSV62576849; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACSL5 | c.1673T>C p.I558T (on ENST00000354273; = p.I614T on NM_016234.3) | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs144236262; called by muse, mutect2, varscan2
- ADAM23 | c.1418C>T p.S473L | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52206610, COSV52221658; called by muse, mutect2, varscan2
- ARHGAP35 | c.2413C>T p.Q805* | Nonsense Mutation (SNP) | VAF 47/135 reads (35%) | catalogued as COSV68328917; called by muse, mutect2, varscan2
- C5orf51 | c.464G>A p.R155K | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT tolerated (0.88); PolyPhen benign (0.007); catalogued as COSV101068919; called by muse, mutect2, varscan2
- DNAH7 | c.3222G>T p.L1074F | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100414553; called by muse, mutect2, varscan2
- DPY19L1 | c.100C>A p.H34N | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.988); catalogued as rs1238383536, COSV100204579; called by muse, mutect2
- FLG2 | c.301A>T p.K101* | Nonsense Mutation (SNP) | VAF 29/102 reads (28%) | catalogued as COSV66166287; called by muse, mutect2, varscan2
- MAP3K13 | c.1663del p.E555Kfs*52 | Frame Shift Del (DEL) | VAF 25/65 reads (38%) | catalogued as COSV53982623; called by mutect2, pindel, varscan2
- MSH5 | c.1603C>G p.L535V | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); catalogued as COSV100994806; called by muse, mutect2
- NOL4L | c.716G>A p.R239H | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV62888998; called by muse, mutect2, varscan2
- PHC3 | c.1009A>G p.I337V (on ENST00000494943 / NM_001308116.2; = p.I349V on NM_024947.4) | Missense Mutation (SNP) | VAF 65/217 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs780757485, COSV71948191; called by muse, mutect2, varscan2
- RABL2B | c.155C>A p.S52Y | Missense Mutation (SNP) | VAF 48/102 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100711477, COSV61483089; called by muse, mutect2, varscan2
- ST8SIA6 | c.394T>A p.C132S | Missense Mutation (SNP) | VAF 43/176 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV66465303; called by muse, mutect2, varscan2
- TTC21A | c.2640G>A p.M880I | Missense Mutation (SNP) | VAF 33/56 reads (59%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV57182819, COSV57189488; called by muse, mutect2, varscan2
- UNC13C | c.4028G>A p.R1343Q | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as rs770064369, COSV52839796, COSV52845310; called by muse, mutect2, varscan2
- ZNF614 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.777); catalogued as COSV54544601; called by muse, mutect2, varscan2
- KMT2C | c.12716_12721del p.S4239_N4240del | In Frame Del (DEL) | VAF 6/53 reads (11%) | called by mutect2, pindel, varscan2
- CCDC170 | c.723A>G p.R241= | Silent (SNP) | VAF 26/35 reads (74%) | catalogued as rs1256643175, COSV53336264; called by muse, mutect2, varscan2
- GALNTL6 | c.192G>A p.L64= | Silent (SNP) | VAF 30/64 reads (47%) | catalogued as COSV72488723, COSV72490836; called by muse, mutect2, varscan2
- ROS1 | c.5205G>A p.T1735= | Silent (SNP) | VAF 83/128 reads (65%) | catalogued as rs146280016, COSV63850731; called by muse, mutect2, varscan2
- SKOR1 | c.2595G>A p.L865= | Silent (SNP) | VAF 13/37 reads (35%) | catalogued as COSV58243615; called by muse, mutect2, varscan2
- SLC2A13 | c.1422T>C p.S474= | Silent (SNP) | VAF 29/92 reads (32%) | catalogued as COSV55110104; called by muse, mutect2, varscan2
- SPTA1 | c.6204G>A p.E2068= | Silent (SNP) | VAF 29/97 reads (30%) | catalogued as COSV63748139; called by muse, mutect2, varscan2
- SYT3 | c.1128G>A p.E376= | Silent (SNP) | VAF 25/61 reads (41%) | catalogued as COSV58895309; called by muse, mutect2, varscan2
- XIRP2 | c.*1031G>A | 3'UTR (SNP) | VAF 3/15 reads (20%) | catalogued as COSV99740917; called by muse, mutect2
